Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4762, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4762-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with renal solid mass – left kidney.

Specimens Submitted:

1: SP: Left renal tumor

2: SP: Fat over tumor of left kidney

DIAGNOSIS:

- 1) KIDNEY, LEFT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR, SOLID AND ACINAR.
- THE TUMOR GREATEST DIAMETER IS 1.1 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- THE SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS INTERSTITIAL FIBROSIS.
- 2) ADIPOSE TISSUE, "OVER TUMOR OF LEFT KIDNEY"; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.

1) The specimen is received fresh for frozen section, labeled "Left Renal Tumor (clip marks base)". It consists of a 2.2 x 2.0 x 1.8 cm partial nephrectomy. The specimen is inked black and sectioned to reveal a 1.1 x 1.0 x 0.8 cm, tan-yellow mass with focal hemorrhage. It located 0.6 cm from the stapled margin. The mass is entirely submitted. The specimen is submitted for TPS.

Summary of Sections:

FSC - frozen section control

MA - mass

2) The specimen is received in formalin, labeled "Fat Over Tumor of Left Kidney". It consists of a 7 x 3 x 2.5 cm segment of tan-yellow, lobulated fatty tissue. Representative sections are submitted.

Summary of Sections:

F - fat

[page 2 of 2]
Summary of Sections:

Part 1: SP: Left renal tumor [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
4	ma	4

Part 2: SP: Fat over tumor of left kidney [REDACTED]

Block	Sect. Site	PCs
3	f	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CONVENTIONAL TYPE, MARGINS FREE. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 11906045-f2fa-4fdd-a535-9ffaec14f9bc (TCGA-BP-4762.31FBDBD3-BE32-4B5B-BF96-AF030F26684D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).